Gene-level copy-number profile of tumor specimen TCGA-43-A474-01A from TCGA case TCGA-43-A474, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 66.5 years (24,286 days).
Specimen TCGA-43-A474-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.c0ea1dd3-4aa5-4d7d-b207-953cdc726f32.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-43-A474-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1ebe59b1-224a-4cf2-a371-6d863f1b8b17

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 1,345; copy number 2: 20,444; copy number 3: 24,583; copy number 4: 8,880; copy number 5: 1,893; copy number 6: 2,416; copy number 7: 216; copy number 8: 11; copy number 9: 5; copy number 13: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-43-A474-01A-11D-A24C-01): tumor purity 0.61, ploidy 2.92, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:4,175,528–4,594,016, 5 genes (within-gene range 0–2): EEF1DP6, LINC01777, AL355602.1, Z98747.1, LINC01646.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 244 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:117,060,326–117,605,770, 12 genes, copy number 13 (within-gene range 4–13): TTF2, MIR942, TRIM45, RPS15AP9, VTCN1, Metazoa_SRP, LINC01525, AL358072.1, MAN1A2, AL157902.2, VPS25P1, AL157902.1.
- chr2:138,669,157–139,733,282, 11 genes, copy number 8 (within-gene range 4–8): NXPH2, RN7SKP286, YY1P2, AHCYP4, AC023468.1, AC013265.1, AC062021.1, AC016710.1, SNORA72, MRPS18BP2, RPL9P13.
- chr5:17,684,584–25,350,073, 69 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr7:79,452,877–86,217,733, 50 genes, copy number 7: MAGI2-AS3, NUP35P2, RNA5SP234, AC073048.1, GNAI1, RNU6-849P, RPL10P11, RN7SL869P, AC003988.1, AC004862.1, RN7SL35P, CD36, SNRPBP1, GNAT3, AC073850.1, SEMA3C, AC004972.1, AC005008.2, AC005008.1, AC004866.1, AC004866.2, EIF4EP4, AC008163.1, DDX43P3, HGF, CACNA2D1, CACNA2D1-AS1, MTHFD2P5, AC004006.1, PCLO, RNA5SP235, AC079799.1, SEMA3E, AC079799.2, AC079987.1, RAD23BP2, SEMA3A, RPL7P30, AC003984.1, AC093716.1, HMGN2P11, AC074183.2, AC074183.1, HNRNPA1P8, SEMA3D, HSPA8P16, DYNLL1P7, LINC00972, AC092013.1, SOCS5P1.
- chr7:89,882,353–90,513,402, 14 genes, copy number 7: STEAP2-AS1, AC004969.1, DPY19L2P4, STEAP1, STEAP2, CFAP69, Y_RNA, AC002064.2, AC002064.1, FAM237B, GTPBP10, AC002064.3, CLDN12, AC006153.1.
- chr7:90,469,639–90,632,568, 3 genes, copy number 7: AC002456.2, AC002456.1, TVP23CP1.
- chr9:71,683,366–73,170,393, 24 genes, copy number 7: CEMIP2, AL671309.1, ABHD17B, Y_RNA, C9orf85, HSPB1P1, C9orf57, AL583829.1, BTF3P4, GDA, AL135924.2, AL135924.1, RNA5SP285, LINC01504, ZFAND5, AL445646.1, AL596448.1, TMC1, RPS20P24, RPS27AP15, LINC01474, ALDH1A1, CYP1D1P, ANXA1.
- chr9:77,177,445–77,648,322, 5 genes, copy number 7 (within-gene range 6–7): VPS13A, GNA14, GNA14-AS1, NUTF2P3, RNU6-1303P.
- chr11:38,498,995–39,161,967, 5 genes, copy number 9: AC021713.1, LINC02759, LINC01493, AC021723.2, AC021723.1.
- chr20:30,484,925–32,101,856, 50 genes, copy number 7: 5_8S_rRNA, AC018688.1, ANKRD20A21P, U6, RNA5SP528, DEFB115, DKKL1P1, AL121723.1, DEFB116, RPL31P3, HAUS6P2, RNA5SP480, DEFB117, DEFB118, AL031650.1, DEFB119, DEFB121, DEFB122, DEFB123, DEFB124, REM1, LINC00028, HM13, AL110115.1, MCTS2P, HM13-IT1, HM13-AS1, AL110115.2, RNU6-384P, ID1, MIR3193, COX4I2, BCL2L1, BCL2L1-AS1, ABALON, TPX2, AL160175.1, MYLK2, FOXS1, DUSP15, TTLL9, RNU1-94P, PDRG1, XKR7, AL031658.2, AL031658.1, RNA5SP481, CCM2L, RNA5SP482, HCK.
- chr20:32,116,171–32,116,629, 1 gene, copy number 7: AL049539.1.

Autosomal genes at a single copy (total copy number 1): 985. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
